Gene-level copy-number profile of tumor specimen TCGA-D1-A1O0-01A from TCGA case TCGA-D1-A1O0, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IA; Tumor grade: G3; Age at diagnosis: 77.1 years (28,162 days).
Specimen TCGA-D1-A1O0-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-UCEC.e24d8eeb-9377-48e2-ba3e-b408d1ce7725.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-D1-A1O0-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 813 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/82fbb943-61ec-43b9-9090-c48b3d575938

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 7; copy number 1: 837; copy number 2: 11,631; copy number 3: 11,173; copy number 4: 31,277; copy number 5: 888; copy number 6: 3,195; copy number 7: 263; copy number 8: 255; copy number 9: 154; copy number 11: 111; copy number 12: 19.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-D1-A1O0-01A-11D-A17C-01): tumor purity 0.85, ploidy 3.58, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 7 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr10:87,859,158–87,971,930, 4 genes: KLLN, PTEN, AC063965.2, RPL11P3.
- chr20:46,997,596–46,998,488, 1 gene: GAPDHP54.
- chr22:28,883,572–29,057,488, 2 genes (within-gene range 0–2): ZNRF3, ZNRF3-IT1.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 284 genes in 15 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:60,912,675–61,056,885, 1 gene, copy number 9: NFIA-AS2.
- chr1:155,316,863–156,500,779, 60 genes, copy number 9–11 (within-gene range 6–11): RUSC1-AS1, RUSC1, ASH1L, MIR555, RNU6-106P, ASH1L-IT1, RNU6-1297P, POU5F1P4, ASH1L-AS1, AL353807.4, DAP3P1, AL353807.1, AL353807.2, MSTO1, AL353807.3, AL353807.5, YY1AP1, DAP3, AL162734.1, MSTO2P, GON4L, AL139128.1, SYT11, U4, RIT1, KHDC4, SNORA80E, SCARNA4, SCARNA4, RXFP4, ARHGEF2, MIR6738, AL355388.1, ARHGEF2-AS1, AL355388.2, SSR2, UBQLN4, LAMTOR2, RAB25, MEX3A, LMNA, SEMA4A, AL135927.1, SLC25A44, PMF1-BGLAP, PMF1, BGLAP, PAQR6, SMG5, TMEM79, GLMP, VHLL, CCT3, TSACC, RHBG, AL139130.1, MIR9-1HG, MIR9-1, MEF2D, Y_RNA.
- chr1:159,958,035–161,470,523, 82 genes, copy number 9 (within-gene range 6–9) (broad region; genes not listed).
- chr1:171,841,498–172,418,466, 1 gene, copy number 9 (within-gene range 6–9): DNM3.
- chr1:172,138,397–172,213,499, 5 genes, copy number 9: DNM3OS, MIR214, MIR3120, MIR199A2, AL137157.1.
- chr1:201,955,503–202,341,980, 18 genes, copy number 12 (within-gene range 6–12): TIMM17A, SNORA70H, RPL10P4, RNPEP, ELF3-AS1, MIR6740, ELF3, AL691482.3, AL691482.1, AL691482.2, Y_RNA, CRIP1P3, GPR37L1, ARL8A, PTPN7, PTPRVP, LGR6, UBE2T.
- chr1:202,369,526–202,370,145, 1 gene, copy number 12: CYCSP4.
- chr3:168,249,522–168,830,599, 1 gene, copy number 9 (within-gene range 3–9): EGFEM1P.
- chr3:168,551,854–169,038,416, 7 genes, copy number 9: MIR551B, RPSAP33, RPL21P43, LINC02082, AC092954.1, AC092954.2, LINC01997.
- chr4:1,550,284–1,982,207, 11 genes, copy number 11 (within-gene range 6–11): AC147067.2, AC147067.1, FAM53A, Y_RNA, SLBP, AC016773.1, TACC3, TMEM129, FGFR3, LETM1, NSD2.
- chr4:15,604,381–16,512,187, 20 genes, copy number 11: FBXL5, FAM200B, AC114744.2, BST1, AC114744.1, AC005798.1, CD38, HPRT1P1, FGFBP1, FGFBP2, PROM1, AC108063.2, TAPT1, AC108063.1, TAPT1-AS1, RPS21P4, AC006427.1, AC006427.2, ZEB2P1, AC097515.1.
- chr13:110,305,812–110,513,209, 1 gene, copy number 9 (within-gene range 4–9): COL4A2.
- chr13:110,456,396–110,561,722, 3 genes, copy number 9: COL4A2-AS2, COL4A2-AS1, RAB20.
- chr20:36,507,702–36,894,235, 14 genes, copy number 11: DLGAP4-AS1, MYL9, Metazoa_SRP, TGIF2, TGIF2-RAB5IF, RAB5IF, SLA2, HNRNPA3P2, NDRG3, Y_RNA, DSN1, SOGA1, RN7SL156P, TLDC2.
- chr20:50,888,916–55,684,915, 59 genes, copy number 9–11 (within-gene range 2–11): ADNP, PSMD10P1, ADNP-AS1, DPM1, MOCS3, AL050404.1, KCNG1, AL121785.1, RPSAP1, NFATC2, MIR3194, ATP9A, AL138807.1, SALL4, LINC01429, RNU6-347P, RNU7-6P, ZFP64, AL109984.1, ERP29P1, LINC01524, AL109610.1, AL049765.2, AL049765.1, MRPS33P4, AL031674.1, AL161945.1, AL121902.1, RPL36P1, TSHZ2, RN7SKP184, AL391097.3, AL391097.1, AL391097.2, AL109930.1, AL354993.1, PPIAP10, AL354993.2, Y_RNA, AL157838.1, ZNF217, AC005808.1, RNU7-14P, AC005914.1, AC006076.1, SUMO1P1, BCAS1, AC005220.1, MIR4756, CYP24A1, AL133335.2, PFDN4, AL133335.1, DOK5, RNU4ATAC7P, RPL12P4, LINC01440, LINC01441, AL160413.1.

Autosomal genes at a single copy (total copy number 1): 834. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
